EXCEPTIONAL_RESPONDERS case ER-ADIN — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c6771896-21ae-4c6c-b575-29ecd65195e6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1955; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: metastasis; Age at diagnosis: 54.1 years (19,760 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic stage: Stage IVB; Prior malignancy: no; Days to last follow up: 2,376 days (6.5 years); Days to best overall response: 1,518 days (4.2 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Carboplatin; Days to treatment start: 1,333 days (3.6 years); Days to treatment end: 1,529 days (4.2 years).
   Treatment given: Therapeutic agents: Paclitaxel; Days to treatment start: 1,333 days (3.6 years).

Follow-up (1 entry)
- Days to follow up: 2,376 days (6.5 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 2,376 days (6.5 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ADIN-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ADIN-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-ADIN-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ADIN-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 45; Percent tumor nuclei: 55; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
